Somatic mutation profile of tumor specimen 0DHMSE from CCDI case PBBSVZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.3 years (2,659 days).
Specimen 0DHMSE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 846381b3-aaf8-4da9-aa99-4f3bc1ab1b06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHMLX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d120ce96-65a3-4624-b834-d7975e7834ce

The open-access MAF lists 42 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Nonsense Mutation 4, Intron 3, RNA 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 660/1113 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1597C>T p.R533C (on ENST00000399959; = p.R534C on NM_001356.5) | Missense Mutation (SNP) | VAF 39/934 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1555954284, COSV67863588, COSV67863748; ClinVar: likely pathogenic; called by muse, mutect2
- NIPBL | c.4495C>T p.Q1499* | Nonsense Mutation (SNP) | VAF 144/1804 reads (8%) | catalogued as rs797045760, COSV56966997, COSV99239299; ClinVar: pathogenic; called by muse, mutect2
- BTBD6 | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 22/394 reads (6%) | catalogued as rs1178525807; called by muse, mutect2
- CAMK1G | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 64/1133 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.606); catalogued as rs144255822; called by muse, mutect2
- DDX3X | c.840G>T p.Q280H (on ENST00000399959; = p.Q281H on NM_001356.5) | Missense Mutation (SNP) | VAF 43/924 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67863407, COSV67864668; called by muse, mutect2
- DDX3X | c.1030G>T p.V344L (on ENST00000399959; = p.V345L on NM_001356.5) | Missense Mutation (SNP) | VAF 161/644 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67864211; called by muse, varscan2
- HBQ1 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 102/231 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs1390964502; called by muse, mutect2, varscan2
- KCNV2 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 34/942 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as CM122524; called by muse, mutect2
- KMT2C | c.3709C>T p.R1237* | Nonsense Mutation (SNP) | VAF 202/578 reads (35%) | catalogued as rs938655561, COSV51498512; called by muse, mutect2, varscan2
- OR1S2 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 360/838 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1160580783; called by muse, mutect2
- PCDHB8 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 12/257 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99175302; called by muse, mutect2
- PPP1R3F | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 141/473 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); catalogued as rs1557121465, COSV50018276; called by muse, mutect2, varscan2
- RYR1 | c.14047G>C p.E4683Q | Missense Mutation (SNP) | VAF 68/1386 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62093661; called by muse, mutect2
- TUBA3C | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 335/749 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.353); catalogued as rs1191887593, COSV101262746, COSV67140213; called by muse, mutect2, varscan2
- CCDC80 | c.450A>C p.R150S | Missense Mutation (SNP) | VAF 178/646 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHST13 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- DDX3X | c.1219G>T p.V407F (on ENST00000399959; = p.V408F on NM_001356.5) | Missense Mutation (SNP) | VAF 64/897 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2
- EFHC2 | c.848A>C p.K283T | Missense Mutation (SNP) | VAF 34/1224 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KATNAL2 | c.916G>C p.A306P (on ENST00000356157 / NM_001353899.1; = p.A234P on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/744 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LSM1 | c.281A>G p.E94G | Missense Mutation (SNP) | VAF 34/1056 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- NCKAP1L | c.2068A>G p.M690V | Missense Mutation (SNP) | VAF 321/775 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR10H3 | c.743C>A p.T248N | Missense Mutation (SNP) | VAF 112/1096 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- PCDHA1 | c.1525T>A p.S509T | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PUS7L | c.510C>A p.N170K | Missense Mutation (SNP) | VAF 237/1165 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3RF3 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 30/854 reads (4%) | called by muse, mutect2
- TSC22D2 | c.784A>T p.T262S | Missense Mutation (SNP) | VAF 87/512 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA1 | c.3615C>G p.T1205= | Silent (SNP) | VAF 38/1408 reads (3%) | called by muse, mutect2
- BRWD3 | c.1770G>T p.V590= | Silent (SNP) | VAF 50/1206 reads (4%) | called by muse, mutect2
- CBX4 | c.816C>T p.N272= | Silent (SNP) | VAF 18/317 reads (6%) | catalogued as rs1014513571, COSV53964788; called by muse, mutect2
- FKBP8 | c.1077G>A p.T359= (on ENST00000222308 / NM_001308373.2; = p.T360= on NM_012181.5) | Silent (SNP) | VAF 37/776 reads (5%) | catalogued as rs1327939291; called by muse, mutect2
- FLT3 | c.1389C>A p.T463= | Silent (SNP) | VAF 93/708 reads (13%) | catalogued as COSV54054327; called by muse, mutect2, varscan2
- KCNB2 | c.966G>A p.Q322= | Silent (SNP) | VAF 87/755 reads (12%) | catalogued as COSV73051538; called by muse, mutect2, varscan2
- LRCH3 | c.648G>A p.A216= | Silent (SNP) | VAF 50/823 reads (6%) | catalogued as rs377726765; called by muse, mutect2
- PAX5 | c.687C>T p.F229= | Silent (SNP) | VAF 28/964 reads (3%) | called by muse, mutect2
- PWWP3B | c.246G>A p.E82= | Silent (SNP) | VAF 34/986 reads (3%) | called by muse, mutect2
- GDI1 | c.991+10G>A | Intron (SNP) | VAF 156/490 reads (32%) | called by muse, mutect2, varscan2
- HDAC6 | c.999+46G>T | Intron (SNP) | VAF 169/422 reads (40%) | called by muse, mutect2, varscan2
- MUC19 | n.5153G>T | RNA (SNP) | VAF 322/797 reads (40%) | called by mutect2, varscan2
- SAP30BP | c.-31G>T | 5'UTR (SNP) | VAF 25/295 reads (8%) | called by muse, mutect2
- SFTA3 | n.1043C>G | RNA (SNP) | VAF 302/730 reads (41%) | called by muse, mutect2, varscan2
- VTI1A | c.264+40dup | Intron (INS) | VAF 66/254 reads (26%) | catalogued as rs780099744; called by mutect2, varscan2
